Somatic mutation profile of tumor specimen MMRF_1627_1_BM_CD138pos (aliquot MMRF_1627_1_BM_CD138pos_T1_KBS5U_L04305) from MMRF case MMRF_1627, project MMRF-COMMPASS (Multiple Myeloma CoMMpass Study). Sex at birth: female; Vital status: Alive; Primary diagnosis: Multiple myeloma; Tissue or organ of origin: Bone marrow; Age at diagnosis: 82.0 years (29,968 days).
Specimen MMRF_1627_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 0247328a-49df-4e1a-8e8e-7831f6d61a59.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MMRF_1627_1_PB_Whole (Blood Derived Normal), aliquot MMRF_1627_1_PB_Whole_C3_KBS5U_L04316; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/26a674de-3189-4ad7-9a8b-8533f9167c4d

The open-access MAF lists 119 somatic variants for this specimen: 43 protein-altering or splice-affecting, 11 silent, 65 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 35, 3'UTR 32, Intron 18, Silent 11, 5'UTR 7, 5'Flank 5, 3'Flank 3, Splice Site 2, Frame Shift Del 2, Nonsense Mutation 2, Splice Region 1, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ACO1 | c.266+1G>A p.X89_splice | Splice Site (SNP) | VAF 60/119 reads (50%) | catalogued as rs1200741849, COSV59379534, COSV59381007; called by muse, mutect2, varscan2
- DUOX1 | c.1525C>T p.R509W | Missense Mutation (SNP) | VAF 66/150 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs757808802, COSV58487385; called by muse, varscan2
- FSTL5 | c.846G>A p.W282* | Nonsense Mutation (SNP) | VAF 50/98 reads (51%) | catalogued as COSV60203532; called by muse, mutect2, varscan2
- IGHV2-70 | c.190A>C p.K64Q | Missense Mutation (SNP) | VAF 40/96 reads (42%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.804); catalogued as rs747883300; called by muse, varscan2
- IGLV3-22 | c.281G>A p.S94N | Missense Mutation (SNP) | VAF 117/244 reads (48%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.733); catalogued as rs756020206; called by muse, mutect2, varscan2
- IGLV3-25 | c.209G>C p.S70T | Missense Mutation (SNP) | VAF 52/116 reads (45%) | SIFT tolerated (0.15); PolyPhen benign (0.007); catalogued as rs145801212; called by muse, varscan2
- ING1 | c.1129G>A p.E377K | Missense Mutation (SNP) | VAF 108/211 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV58167057; called by muse, mutect2, varscan2
- MYSM1 | c.701C>T p.S234F | Missense Mutation (SNP) | VAF 55/203 reads (27%) | SIFT tolerated (0.19); PolyPhen benign (0.003); catalogued as rs756651898, COSV68978091; called by muse, mutect2, varscan2
- REEP4 | c.374G>T p.G125V | Missense Mutation (SNP) | VAF 36/84 reads (43%) | SIFT deleterious (0); PolyPhen possibly damaging (0.651); catalogued as rs763817191; called by muse, mutect2, varscan2
- REV3L | c.8212A>C p.N2738H | Missense Mutation (SNP) | VAF 113/236 reads (48%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); catalogued as rs1448911997; called by muse, mutect2, varscan2
- SCARA5 | c.241G>A p.V81M | Missense Mutation (SNP) | VAF 23/47 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs1008506987; called by muse, mutect2, varscan2
- SCN11A | c.5356G>A p.G1786S | Missense Mutation (SNP) | VAF 35/75 reads (47%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.276); catalogued as rs1450725387; called by muse, mutect2, varscan2
- SCN9A | c.5579G>A p.R1860H (on ENST00000303354; = p.R1849H on NM_002977.3) | Missense Mutation (SNP) | VAF 25/54 reads (46%) | SIFT tolerated (0.07); PolyPhen benign (0.091); catalogued as rs766124857, COSV100312733; called by muse, mutect2, varscan2
- SYNPO2 | c.1205G>A p.R402Q | Missense Mutation (SNP) | VAF 72/147 reads (49%) | SIFT tolerated (1); PolyPhen benign (0.011); catalogued as rs951901344; called by muse, mutect2, varscan2
- TERF1 | c.1108G>A p.V370I (on ENST00000276603 / NM_017489.3; = p.V350I on NM_003218.4) | Missense Mutation (SNP) | VAF 39/88 reads (44%) | SIFT tolerated (0.21); PolyPhen benign (0.054); catalogued as rs771909875; called by muse, mutect2, varscan2
- ARMC5 | c.200T>C p.L67P | Missense Mutation (SNP) | VAF 22/43 reads (51%) | SIFT deleterious (0); PolyPhen benign (0.035); called by muse, mutect2, varscan2
- BRS3 | c.448G>A p.V150M | Missense Mutation (SNP) | VAF 104/323 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CABP5 | c.271G>C p.E91Q | Missense Mutation (SNP) | VAF 19/206 reads (9%) | SIFT tolerated (0.07); PolyPhen benign (0.056); called by muse, mutect2
- CD109 | c.142del p.L48Ffs*9 | Frame Shift Del (DEL) | VAF 20/60 reads (33%) | called by mutect2, pindel, varscan2
- CHKB | c.344C>A p.S115Y | Missense Mutation (SNP) | VAF 54/58 reads (93%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); called by muse, mutect2, varscan2
- DNAH14 | c.6247G>C p.D2083H (on ENST00000445597; = p.D2736H on NM_001367479.1) | Missense Mutation (SNP) | VAF 9/112 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- DOCK4 | c.1340G>A p.G447E | Missense Mutation (SNP) | VAF 35/74 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- DZIP1 | c.1786G>T p.E596* (on ENST00000347108; = p.E577* on NM_014934.5) | Nonsense Mutation (SNP) | VAF 7/55 reads (13%) | called by muse, mutect2, varscan2
- FAM20B | c.1141A>C p.S381R | Missense Mutation (SNP) | VAF 127/532 reads (24%) | SIFT tolerated (0.62); PolyPhen benign (0.02); called by muse, mutect2, varscan2
- GPN2 | c.621C>A p.D207E | Missense Mutation (SNP) | VAF 17/65 reads (26%) | SIFT tolerated (0.67); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- KBTBD13 | c.514G>A p.D172N | Missense Mutation (SNP) | VAF 17/35 reads (49%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.84); called by muse, mutect2, varscan2
- LARP4B | c.1898G>T p.C633F | Missense Mutation (SNP) | VAF 65/141 reads (46%) | SIFT deleterious (0.01); PolyPhen benign (0.352); called by muse, mutect2, varscan2
- MAP4K3 | c.362del p.L121Rfs*17 | Frame Shift Del (DEL) | VAF 12/50 reads (24%) | called by mutect2, pindel, varscan2
- MCTP1 | c.2270C>T p.P757L | Missense Mutation (SNP) | VAF 28/61 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- MSLN | c.1077C>T p.L359= | Splice Region (SNP) | VAF 77/165 reads (47%) | called by muse, mutect2, varscan2
- NDST3 | c.2323G>A p.D775N | Missense Mutation (SNP) | VAF 11/68 reads (16%) | SIFT tolerated (0.61); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- NKX2-2 | c.190C>G p.P64A | Missense Mutation (SNP) | VAF 19/112 reads (17%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.452); called by muse, mutect2, varscan2
- PCSK5 | c.3141G>T p.L1047F | Missense Mutation (SNP) | VAF 11/225 reads (5%) | SIFT tolerated (0.38); PolyPhen benign (0.086); called by muse, mutect2
- PTP4A2 | c.-593-2A>G | Splice Site (SNP) | VAF 159/338 reads (47%) | called by muse, mutect2, varscan2
- RUBCNL | c.1190A>C p.K397T | Missense Mutation (SNP) | VAF 8/40 reads (20%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.564); called by muse, mutect2
- SPHKAP | c.835C>A p.P279T | Missense Mutation (SNP) | VAF 9/264 reads (3%) | SIFT tolerated (0.2); PolyPhen benign (0.005); called by muse, mutect2
- TXNDC11 | c.1274C>A p.A425D (on ENST00000356957 / NM_001303447.2; = p.A398D on NM_015914.7 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 34/67 reads (51%) | SIFT tolerated (0.18); PolyPhen benign (0.111); called by muse, mutect2, varscan2
- UGGT1 | c.1661C>A p.A554E | Missense Mutation (SNP) | VAF 41/189 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.721); called by muse, varscan2
- VCP | c.1807C>A p.Q603K | Missense Mutation (SNP) | VAF 65/129 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- WDR7 | c.1874C>G p.A625G | Missense Mutation (SNP) | VAF 53/108 reads (49%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.978); called by muse, mutect2, varscan2
- XPNPEP2 | c.358_359insT p.Q120Lfs*3 | Frame Shift Ins (INS) | VAF 16/35 reads (46%) | called by mutect2, pindel, varscan2
- YEATS2 | c.2767A>C p.K923Q | Missense Mutation (SNP) | VAF 76/180 reads (42%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.991); called by mutect2, varscan2
- ZNF721 | c.2391T>A p.F797L (on ENST00000338977; = p.F809L on NM_133474.4) | Missense Mutation (SNP) | VAF 103/107 reads (96%) | SIFT deleterious (0); PolyPhen benign (0.232); called by muse, mutect2, varscan2
- CRP | c.674G>A p.*225= | Silent (SNP) | VAF 12/36 reads (33%) | called by muse, mutect2, varscan2
- HES7 | c.153G>A p.P51= | Silent (SNP) | VAF 13/125 reads (10%) | catalogued as rs1180587901; called by muse, mutect2, varscan2
- IGHV2-70 | c.75G>A p.E25= | Silent (SNP) | VAF 39/87 reads (45%) | catalogued as rs181122105; called by muse, varscan2
- NXPE3 | c.798T>C p.G266= | Silent (SNP) | VAF 33/146 reads (23%) | called by muse, varscan2
- OR10G7 | c.486T>A p.T162= | Silent (SNP) | VAF 65/280 reads (23%) | called by muse, mutect2, varscan2
- RYR3 | c.9405C>T p.P3135= (on ENST00000389232; = p.P3136= on NM_001036.6) | Silent (SNP) | VAF 36/221 reads (16%) | catalogued as COSV101211981; called by muse, mutect2, varscan2
- SKOR2 | c.33C>T p.D11= | Silent (SNP) | VAF 32/80 reads (40%) | catalogued as rs1391433313; called by muse, mutect2, varscan2
- SLC6A15 | c.603T>G p.S201= | Silent (SNP) | VAF 37/202 reads (18%) | called by muse, mutect2, varscan2
- SLITRK5 | c.1603C>T p.L535= | Silent (SNP) | VAF 16/154 reads (10%) | called by muse, mutect2
- WDR90 | c.2715G>A p.S905= | Silent (SNP) | VAF 28/57 reads (49%) | catalogued as rs376123449; called by muse, mutect2, varscan2
- ZSCAN10 | c.966G>T p.L322= (on ENST00000252463; = p.L377= on NM_032805.3) | Silent (SNP) | VAF 14/54 reads (26%) | called by muse, mutect2, varscan2
- AEN | c.*1482G>C | 3'UTR (SNP) | VAF 18/47 reads (38%) | called by muse, mutect2, varscan2
- AMBRA1 | c.2421-78G>A | Intron (SNP) | VAF 28/80 reads (35%) | called by muse, mutect2
- AMOT | c.*3307del | 3'UTR (DEL) | VAF 36/95 reads (38%) | called by mutect2, pindel, varscan2
- AP000769.5 | chr11:65499163 A>G | 5'Flank (SNP) | VAF 21/41 reads (51%) | catalogued as rs879025593; called by muse, mutect2, varscan2
- AP000769.5 | chr11:65499265 T>C | 5'Flank (SNP) | VAF 36/93 reads (39%) | catalogued as rs534838156; called by muse, mutect2, varscan2
- AP3B2 | c.360+1701T>G | Intron (SNP) | VAF 5/10 reads (50%) | called by muse, mutect2, varscan2
- ARMC10 | c.*1116T>A | 3'UTR (SNP) | VAF 4/16 reads (25%) | called by muse, mutect2, varscan2
- ASH1L | chr1:155563260 G>A | 5'Flank (SNP) | VAF 48/175 reads (27%) | catalogued as rs1292258145; called by muse, mutect2, varscan2
- ATP8A2 | c.*5288C>T | 3'UTR (SNP) | VAF 11/44 reads (25%) | called by muse, mutect2, varscan2
- BCL7A | chr12:122021245 G>A | 5'Flank (SNP) | VAF 65/121 reads (54%) | catalogued as COSV55851570; called by muse, mutect2, varscan2
- BTBD9 | c.*4425G>A | 3'UTR (SNP) | VAF 37/109 reads (34%) | called by muse, mutect2, varscan2
- C9orf131 | c.231+77C>G | Intron (SNP) | VAF 23/86 reads (27%) | called by muse, mutect2, varscan2
- CACHD1 | c.*391G>A | 3'UTR (SNP) | VAF 15/69 reads (22%) | called by muse, mutect2, varscan2
- CACNA1C | chr12:2053389 T>A | 5'Flank (SNP) | VAF 38/67 reads (57%) | called by muse, mutect2, varscan2
- CENPF | c.*418C>T | 3'UTR (SNP) | VAF 192/414 reads (46%) | called by muse, mutect2, varscan2
- DAPK1 | c.1924-16C>A | Intron (SNP) | VAF 22/100 reads (22%) | called by muse, mutect2, varscan2
- DENND1B | c.*5364dup | 3'UTR (INS) | VAF 19/148 reads (13%) | called by mutect2, pindel, varscan2
- DIPK2A | c.-29C>T | 5'UTR (SNP) | VAF 11/23 reads (48%) | called by muse, mutect2, varscan2
- DMRTB1 | c.*431A>T | 3'UTR (SNP) | VAF 12/27 reads (44%) | called by muse, mutect2, varscan2
- ERICH3 | c.-34A>G | 5'UTR (SNP) | VAF 26/28 reads (93%) | called by muse, mutect2, varscan2
- FBXO3 | c.1240-1444T>A | Intron (SNP) | VAF 104/216 reads (48%) | catalogued as rs1436693008; called by muse, mutect2, varscan2
- FEN1 | c.*454G>A | 3'UTR (SNP) | VAF 67/130 reads (52%) | catalogued as rs1354177186; called by muse, mutect2, varscan2
- FIBIN | c.*937G>C | 3'UTR (SNP) | VAF 21/103 reads (20%) | called by muse, mutect2
- GPR158 | c.*2555T>A | 3'UTR (SNP) | VAF 44/89 reads (49%) | called by muse, mutect2, varscan2
- GRIK4 | c.-20T>G | 5'UTR (SNP) | VAF 36/95 reads (38%) | called by muse, mutect2, varscan2
- GRIN1 | c.*748C>T | 3'UTR (SNP) | VAF 55/193 reads (28%) | called by muse, mutect2, varscan2
- GSDMD | c.411-157C>T | Intron (SNP) | VAF 51/95 reads (54%) | catalogued as rs1429894859; called by muse, mutect2, varscan2
- IGLC3 | c.*42A>T | 3'UTR (SNP) | VAF 72/160 reads (45%) | called by muse, mutect2, varscan2
- IGSF22 | c.2096-1510A>C | Intron (SNP) | VAF 54/109 reads (50%) | called by muse, mutect2, varscan2
- KCTD12 | c.*2646C>T | 3'UTR (SNP) | VAF 14/82 reads (17%) | called by muse, mutect2, varscan2
- LONRF2 | c.*3172G>T | 3'UTR (SNP) | VAF 27/105 reads (26%) | called by muse, mutect2, varscan2
- LSM3 | c.*2151C>T | 3'UTR (SNP) | VAF 33/106 reads (31%) | called by muse, mutect2, varscan2
- LTB | c.163-119G>T | Intron (SNP) | VAF 123/272 reads (45%) | catalogued as COSV53000283, COSV53001753; called by muse, mutect2, varscan2
- MAGEA1 | c.-4C>T | 5'UTR (SNP) | VAF 43/308 reads (14%) | called by muse, mutect2, varscan2
- MDGA2 | c.281-41665A>C | Intron (SNP) | VAF 57/118 reads (48%) | catalogued as rs767185527, COSV62104477; called by muse, mutect2, varscan2
- MDH1B | c.-37C>T | 5'UTR (SNP) | VAF 12/263 reads (5%) | called by muse, mutect2
- MLLT6 | c.*2965C>G | 3'UTR (SNP) | VAF 39/79 reads (49%) | called by muse, mutect2, varscan2
- MN1 | c.*2454del | 3'UTR (DEL) | VAF 24/276 reads (9%) | called by mutect2, pindel
- MRAP2 | c.*657A>G | 3'UTR (SNP) | VAF 64/123 reads (52%) | called by muse, mutect2, varscan2
- PASK | c.*11C>T | 3'UTR (SNP) | VAF 130/303 reads (43%) | called by muse, mutect2, varscan2
- PCYOX1L | c.*783C>G | 3'UTR (SNP) | VAF 18/95 reads (19%) | called by muse, mutect2, varscan2
- RABGEF1 | chr7:66810950 A>T | 3'Flank (SNP) | VAF 9/73 reads (12%) | called by muse, mutect2, varscan2
- RARB | chr3:25597061 G>A | 3'Flank (SNP) | VAF 74/173 reads (43%) | catalogued as rs935111817; called by muse, mutect2, varscan2
- RNF152 | c.*2436del | 3'UTR (DEL) | VAF 61/134 reads (46%) | catalogued as rs944588011; called by mutect2, varscan2
- RTN4 | c.3013+14934A>C | Intron (SNP) | VAF 30/815 reads (4%) | called by muse, mutect2
- RUNX1 | c.724+13127C>A | Intron (SNP) | VAF 18/47 reads (38%) | called by muse, mutect2, varscan2
- SOX11 | c.*494C>A | 3'UTR (SNP) | VAF 16/35 reads (46%) | catalogued as rs1056961081, COSV58984915; called by muse, mutect2, varscan2
- SOX17 | c.*830C>A | 3'UTR (SNP) | VAF 21/49 reads (43%) | called by muse, mutect2, varscan2
- SSR1 | c.*3664T>A | 3'UTR (SNP) | VAF 122/233 reads (52%) | called by muse, mutect2, varscan2
- TNKS | c.*1195G>A | 3'UTR (SNP) | VAF 11/118 reads (9%) | called by muse, mutect2
- TPT1 | c.-80G>A | 5'UTR (SNP) | VAF 14/46 reads (30%) | called by muse, mutect2, varscan2
- TRIOBP | c.6324+886G>C | Intron (SNP) | VAF 11/145 reads (8%) | called by muse, mutect2
- UVRAG | c.-74T>G | 5'UTR (SNP) | VAF 22/43 reads (51%) | called by muse, mutect2, varscan2
- VIPR2 | c.*1719G>T | 3'UTR (SNP) | VAF 48/335 reads (14%) | catalogued as rs1484383397; called by muse, mutect2, varscan2
- VPS13D | c.*2807G>A | 3'UTR (SNP) | VAF 43/98 reads (44%) | catalogued as rs939976786; called by muse, mutect2, varscan2
- VSX1 | chr20:25071617 A>G | 3'Flank (SNP) | VAF 21/77 reads (27%) | called by muse, mutect2, varscan2
- WDFY1 | c.*1246C>T | 3'UTR (SNP) | VAF 64/138 reads (46%) | called by muse, mutect2, varscan2
- WDR41 | c.*1683C>G | 3'UTR (SNP) | VAF 26/133 reads (20%) | called by muse, mutect2, varscan2
- WSB1 | c.711+691G>A | Intron (SNP) | VAF 4/18 reads (22%) | called by muse, mutect2
- Z98752.3 | c.201+9187C>A | Intron (SNP) | VAF 39/74 reads (53%) | called by muse, mutect2, varscan2
- ZNF140 | c.10-596T>G | Intron (SNP) | VAF 35/71 reads (49%) | called by muse, mutect2, varscan2
- ZNF277 | c.293+1103G>A | Intron (SNP) | VAF 40/83 reads (48%) | called by muse, mutect2, varscan2
- ZNF598 | c.1292+13G>T | Intron (SNP) | VAF 42/106 reads (40%) | called by muse, mutect2, varscan2
- ZNF681 | c.*4299G>A | 3'UTR (SNP) | VAF 77/139 reads (55%) | called by muse, mutect2, varscan2
- ZSWIM9 | c.588+3931A>C | Intron (SNP) | VAF 8/84 reads (10%) | called by muse, mutect2
